Gene-level copy-number profile of tumor specimen C3L-08266-04 from CPTAC case C3L-08266, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 70.9 years (25,910 days).
Specimen C3L-08266-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4311a7e3-b7d0-433d-ba11-93ff7bf33d9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-08266-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/35a2b5f4-d612-4fa8-a430-2efc566bca63

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 3,827; copy number 2: 44,698; copy number 3: 9,417; copy number 4: 667; copy number 5: 48; copy number 6: 188; copy number 8: 20; copy number 10: 7; copy number 14: 1; copy number 18: 4; copy number 21: 3.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:102,453,367–102,453,792, 1 gene: AL357139.1.
- chr13:39,655,627–39,791,665, 3 genes (within-gene range 0–3): COG6, MIR4305, RNY4P14.
- chr13:55,174,454–55,174,548, 1 gene: MIR5007.
- chr14:26,443,090–26,598,033, 2 genes: NOVA1, AL079343.1.
- chr15:47,133,495–47,134,122, 1 gene: AC066615.1.
- chr17:22,671,433–22,706,703, 2 genes (within-gene range 0–2): AC131274.3, AC131274.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 258 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,009,982–89,020,686, 2 genes, copy number 6 (within-gene range 3–6): IGKV1-9, IGKV2-10.
- chr2:89,040,224–91,843,802, 85 genes, copy number 6 (broad region; genes not listed).
- chr9:63,728,877–64,487,069, 19 genes, copy number 6: AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3.
- chr9:64,621,560–66,952,344, 45 genes, copy number 5: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P, CDRT15P12, RBPJP2, RAB28P4, ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1, AL353770.4.
- chr9:67,697,076–68,531,061, 20 genes, copy number 8: Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr10:42,149,310–42,149,549, 1 gene, copy number 5: KSR1P1.
- chr14:18,333,726–18,596,310, 7 genes, copy number 10–18 (within-gene range 3–18): CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13.
- chr16:32,809,556–32,824,645, 2 genes, copy number 5: AC137761.1, AC137761.2.
- chr16:46,469,341–46,569,097, 1 gene, copy number 14 (within-gene range 4–14): ANKRD26P1.
- chr19:24,146,701–24,163,425, 2 genes, copy number 6: AC073534.2, AC073534.1.
- chr21:7,744,962–13,120,807, 74 genes, copy number 6–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,010. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
